Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5508, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5508-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a serum PSA level of 7.4 ng/ml. He has a family history of prostate cancer.

The patient also has a history of [REDACTED]

The patient had and outside prostate biopsy (not reviewed at [REDACTED] reported as prostatic adenocarcinoma: left apex (Gleason score 3+3=6), left mid (Gleason score 3+4=7), left base (Gleason score 3+3=6), right apex (Gleason score 3+3=6), right mid (Gleason score 3+3=6), and right base (Gleason score 3+3=6). The clinical stage is T1c.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

CGA - EJ - 5508

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, EXCISION -

FOUR BENIGN LYMPH NODES (0/4). NO EVIDENCE OF MALIGNANCY.

PART 3: LEFT PELVIC LYMPH NODES, EXCISION -

THIRTEEN BENIGN LYMPH NODES (0/13). NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+4=7, WITH A TERTIARY FOCUS OF GLEASON PATTERN 5 PROSTATIC ADENOCARCINOMA (See comment).
- B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES OF THE PROSTATE GLAND AND HAS A MAXIMAL TUMOR DIAMETER OF 2 CM IN A HISTOLOGIC SECTION.
- C. CARCINOMA COMPRISES APPROXIMATELY 15% OF THE SAMPLED PROSTATE GLAND VOLUME.
- D. FOCAL CARCINOMATOUS EXTRACAPSULAR EXTENSION IS PRESENT IN THE RIGHT POSTERIOR MID AND RIGHT POSTERIOR BASE PROSTATE (SECTIONS 3V, 3WW).
- E. MULTIFOCAL CARCINOMATOUS PERINEURAL INVASION IS PRESENT.
- F. NO ANGIOLYMPHATIC INVASION IS PRESENT.
- G. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.
- H. BENIGN SEMINAL VESICLES AND DISTAL VASA DEFERENTIA.
- I. ALL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- J. NON-NEOPLASTIC PROSTATE WITH MILD NODULAR HYPERPLASIA AND FOCAL GLANDULAR ATROPHY.
- K. TNM PATHOLOGIC STAGE: T3a N0 MX.
- L. HISTOLOGIC GRADE: G3-4 (See synoptic).

COMMENT:

Part 3: There is a small (0.3 cm) focus of Gleason pattern 5 carcinoma present in the left mid anterior-posterior prostate (slides 30, 3V). This likely represents a small focus of dedifferentiation of the prostatic adenocarcinoma. Gleason 4 and 5 components comprise approximately 20% of the total sampled tumor volume.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 7.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	54.97gm
TUMOR SIZE:	Maximum dimension: 2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Focal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor

LYMPH NODES EXAMINED:	17
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated
Comment:	There is a 0.3 cm focus of Gleason pattern 5 carcinoma present in the left mid anterior-posterior prostate (slides 30, 3V).

Source: NCI Genomic Data Commons file bb52eabc-d073-4b64-ae5e-c0b1a3543f8b (TCGA-EJ-5508.D2590559-0EB6-479E-BA3A-B59C3429CA6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).